Somatic mutation profile of tumor specimen MP2PRT-PATRPS-TBP1-A (aliquot MP2PRT-PATRPS-TBP1-A-1-0-D-A81Y-36) from MP2PRT case MP2PRT-PATRPS, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.2 years (5,925 days).
Specimen MP2PRT-PATRPS-TBP1-A: Sample type: Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Whole Blood; Biospecimen anatomic site: Blood; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb8b9a1b-dcd6-4e20-9461-c379beb59c36.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATRPS-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATRPS-NB1-A-1-0-D-A81Y-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/96ae6985-db43-451a-9d7f-8af27cd059e8

The open-access MAF lists 25 somatic variants for this specimen: 18 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Nonsense Mutation 3, Frame Shift Ins 1, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDRT15L2 | c.106C>T p.R36C | Missense Mutation (SNP) | VAF 36/583 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs567353433; called by muse, mutect2
- HYDIN | c.244G>T p.E82* | Nonsense Mutation (SNP) | VAF 36/205 reads (18%) | catalogued as COSV55481517; called by muse, mutect2, varscan2
- KIF17 | c.3049C>T p.R1017C | Missense Mutation (SNP) | VAF 32/392 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs147784710; called by muse, mutect2
- MTA1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 36/732 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164967046, COSV58759745; called by muse, mutect2
- NF1 | c.6820-1G>T p.X2274_splice (on ENST00000358273 / NM_001042492.3; = p.X2253_splice on NM_000267.3) | Splice Site (SNP) | VAF 109/252 reads (43%) | catalogued as CS1311545, CS134549, COSV62201674, COSV62227637; called by muse, mutect2, varscan2
- OBSL1 | c.4708G>A p.G1570R | Missense Mutation (SNP) | VAF 66/577 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as rs550340452; called by muse, mutect2, varscan2
- PREPL | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 56/305 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs766402014; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TNFSF15 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 50/398 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758572471; called by muse, mutect2, varscan2
- TTC7B | c.2081C>T p.T694M | Missense Mutation (SNP) | VAF 45/576 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs201941721, COSV60637218; called by muse, mutect2
- TTN | c.35514dup p.P11839Tfs*18 (on ENST00000591111; = p.P10912Tfs*18 on NM_133378.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 54/234 reads (23%) | catalogued as rs1417338194; called by mutect2, pindel, varscan2
- UNC79 | c.3878G>T p.S1293I (on ENST00000393151 / NM_001346218.2; = p.S1116I on NM_020818.5) | Missense Mutation (SNP) | VAF 58/756 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV56386019; called by muse, mutect2
- ZNF503 | c.1456G>A p.A486T | Missense Mutation (SNP) | VAF 22/708 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0.073); catalogued as rs1471936316; called by muse, mutect2
- DST | c.18884A>T p.K6295I (on ENST00000361203 / NM_001374722.1; = p.K3992I on NM_015548.5) | Missense Mutation (SNP) | VAF 64/454 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ERCC6L | c.1513C>T p.R505* | Nonsense Mutation (SNP) | VAF 52/596 reads (9%) | called by muse, mutect2
- FAM189A2 | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT tolerated (0.3); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FSHR | c.1598C>A p.S533Y | Missense Mutation (SNP) | VAF 20/558 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.255); called by muse, mutect2
- SAMD9L | c.730A>T p.K244* | Nonsense Mutation (SNP) | VAF 42/463 reads (9%) | called by muse, mutect2
- ZBTB44 | c.115G>A p.D39N | Missense Mutation (SNP) | VAF 43/487 reads (9%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.998); called by muse, mutect2
- ASMT | c.78C>T p.F26= | Silent (SNP) | VAF 56/518 reads (11%) | catalogued as rs368151541; called by muse, mutect2, varscan2
- MAGEB3 | c.213C>A p.T71= | Silent (SNP) | VAF 80/535 reads (15%) | called by muse, mutect2, varscan2
- MATN2 | c.1269C>T p.S423= | Silent (SNP) | VAF 28/352 reads (8%) | called by muse, mutect2
- OR2H2 | c.219G>A p.T73= | Silent (SNP) | VAF 208/921 reads (23%) | catalogued as rs111578865; called by muse, mutect2, varscan2
- SLC12A1 | c.3228C>T p.I1076= | Silent (SNP) | VAF 30/396 reads (8%) | catalogued as rs1213662310, COSV66791678; called by muse, mutect2
- ZNF557 | c.1248G>A p.T416= (on ENST00000414706 / NM_001044388.2; = p.T423= on NM_024341.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/127 reads (17%) | catalogued as rs377424039; called by muse, mutect2, varscan2
- RHBDD1 | c.857-7079A>G | Intron (SNP) | VAF 36/333 reads (11%) | called by muse, mutect2
